Gene-level copy-number profile of tumor specimen TARGET-40-PAMHYN-01A from TARGET case TARGET-40-PAMHYN, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 9.6 years (3,499 days).
Specimen TARGET-40-PAMHYN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.3cb1ff4f-3324-52a6-82fa-2f61a2f8c7ed.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAMHYN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate.
https://portal.gdc.cancer.gov/files/427c1c16-a2f7-4366-8ec4-07b7ab136652

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 558; copy number 1: 1,215; copy number 2: 20,852; copy number 3: 15,341; copy number 4: 13,080; copy number 5: 4,507; copy number 6: 1,326; copy number 7: 1,068; copy number 8: 1,543; copy number 9: 117; copy number 10: 49; copy number 11: 147; copy number 12: 99; copy number 13: 90; copy number 14: 89; copy number 15: 11; copy number 16: 87; copy number 18: 9; copy number 19: 32.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–54,346, 2 genes: LINC01986, AC066595.1.
- chr3:116,582,552–117,027,039, 9 genes: RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr3:175,059,361–175,115,242, 2 genes: EEF1B2P8, NAALADL2-AS3.
- chr5:165,782,805–166,382,599, 5 genes: AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1.
- chr9:21,929,457–21,967,751, 2 genes: ERVFRD-3, CDKN2A-DT.
- chr10:69,630,247–70,170,523, 10 genes: FAM241B, LINC02651, RPL5P26, COL13A1, LINC02636, MACROH2A2, AIFM2, TYSND1, SAR1A, CALM2P2.
- chr10:87,817,928–88,049,823, 8 genes (within-gene range 0–1): CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,174 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:67,685,201–86,456,553, 245 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:197,569–503,905, 12 genes, copy number 6: AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, AC093326.2.
- chr2:779,840–7,450,544, 81 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:23,330,664–23,708,611, 6 genes, copy number 5 (within-gene range 4–5): AC012506.1, AC012506.3, AC012506.2, AC012506.4, KLHL29, AC011239.1.
- chr2:88,170,274–94,604,573, 135 genes, copy number 5–7 (broad region; genes not listed).
- chr2:96,184,859–96,552,634, 11 genes, copy number 8 (within-gene range 2–8): STARD7, STARD7-AS1, TMEM127, CIAO1, SNRNP200, AC021188.1, ITPRIPL1, NCAPH, NEURL3, AC013270.1, ARID5A.
- chr2:98,331,389–103,623,830, 92 genes, copy number 6–9 (broad region; genes not listed).
- chr2:158,847,619–159,286,703, 11 genes, copy number 5: AC064843.1, OR7E89P, OR7E28P, OR7E90P, RNU2-21P, TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888, WDSUB1.
- chr4:30,718,805–31,211,678, 5 genes, copy number 5: AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497.
- chr4:48,986,275–55,161,880, 81 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr4:94,117,792–95,868,764, 15 genes, copy number 5: AC096746.1, HMGB3P15, SMARCAD1, HPGDS, AC109925.1, RPL35AP11, PDLIM5, AC108067.1, BMPR1B-DT, BMPR1B, UNC5C, AC106881.1, RPL30P6, PDHA2, RNU6-1059P.
- chr5:1,798,385–16,192,709, 219 genes, copy number 5 (broad region; genes not listed).
- chr5:31,820,564–32,888,145, 24 genes, copy number 5: RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1, NPR3, AC025459.1.
- chr5:32,947,443–33,026,025, 3 genes, copy number 5: LINC02120, AC034223.1, AC034223.2.
- chr5:34,883,057–40,312,905, 90 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr5:93,360,779–114,668,410, 250 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr6:36,639,545–45,664,349, 237 genes, copy number 9–18 (within-gene range 4–18) (broad region; genes not listed).
- chr6:48,754,649–49,116,115, 4 genes, copy number 5 (within-gene range 4–5): AL391538.1, AL022099.1, AL589994.1, AL589994.2.
- chr7:6,016,877–159,233,377, 2,877 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:33,591,330–36,321,404, 28 genes, copy number 16: DUSP26, AF279873.3, BUD31P1, RN7SL457P, VENTXP5, AF279873.2, AF279873.1, AF279873.4, AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41, AP006245.1, RNU6-533P, AP006245.2.
- chr8:46,028,804–145,066,685, 1,533 genes, copy number 5–8 (broad region; genes not listed).
- chr9:33,921,693–41,701,096, 276 genes, copy number 6–11 (broad region; genes not listed).
- chr10:78,943,328–80,041,044, 40 genes, copy number 5: ZMIZ1-AS1, AL356753.1, ZMIZ1, PPIF, ZCCHC24, AL133481.1, TPRX1P1, AL133481.3, AL133481.2, EIF5AL1, BX248123.1, RPS12P18, SFTPA2, MBL3P, SFTPA3P, SFTPA1, LINC02679, AL132656.2, NUTM2B-AS1, AL132656.3, AL132656.4, BEND3P3, AL132656.1, NUTM2B, AL135925.1, NUTM2E, NPAP1P2, CTSLP6, PGGT1BP2, AL512662.1, BMS1P21, MBL1P, SFTPD, SFTPD-AS1, ZNRF2P3, DPY19L2P5, AL356095.1, C1DP3, C1DP2, C1DP4.
- chr11:38,013,510–49,434,438, 221 genes, copy number 6–19 (within-gene range 2–19) (broad region; genes not listed).
- chr12:7,812,512–7,976,360, 11 genes, copy number 5: SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6, Y_RNA.
- chr13:31,063,306–32,299,125, 13 genes, copy number 5 (within-gene range 2–5): WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1, RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1.
- chr14:18,333,726–21,622,567, 196 genes, copy number 5 (broad region; genes not listed).
- chr14:105,764,503–106,461,055, 117 genes, copy number 7 (broad region; genes not listed).
- chr15:68,749,501–68,820,897, 3 genes, copy number 6 (within-gene range 4–6): CARS1P1, ANP32A, MIR4312.
- chr15:72,241,181–73,634,134, 39 genes, copy number 5–7: PARP6, AC009690.3, AC009690.2, CELF6, AC009690.1, HEXA, HEXA-AS1, RPL12P35, TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, AC103874.1, NPM1P42, NEO1, FKBP1AP2, NPM1P43, AC068397.1, HCN4, AC068397.2, REC114, MRPS15P1, NPTN, NPTN-IT1.
- chr15:86,079,973–87,029,052, 1 gene, copy number 6 (within-gene range 4–6): AGBL1.
- chr15:86,295,649–101,078,257, 323 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr17:7,686,071–20,896,140, 497 genes, copy number 5–19 (within-gene range 3–19) (broad region; genes not listed).
- chr17:34,319,435–35,089,319, 15 genes, copy number 5 (within-gene range 2–5): CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1, AC022903.1, CCT6B, AC022903.2, ZNF830, LIG3, RFFL.
- chr18:49,739,823–51,845,628, 43 genes, copy number 5: AC090227.3, ACAA2, AC090227.2, SNHG22, SCARNA17, AC090227.1, MYO5B, Y_RNA, RNA5SP457, AC091044.1, ADAD1P2, AC105224.1, MIR4320, RN7SL310P, CFAP53, AC090246.1, MBD1, CXXC1, AC105227.1, AC105227.2, RNA5SP458, SKA1, RPLP0P11, MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3.
- chr18:63,123,346–68,114,878, 52 genes, copy number 6–7: BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD, AC009802.1, SERPINB8, LINC01924, RPL12P39, LINC00305, LINC01538, AC027506.1, AC090348.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19, RNU6-1037P, MIR5011, RPL31P9, AC091042.1, AC110597.1, DSEL, AC110597.3, AC114689.3, AC022662.1, AC022655.1, FAM32DP, AC114689.1, LINC01903, AC114689.2, AC100844.1, AC068112.1.
- chr20:45,833,799–46,550,654, 31 genes, copy number 5: SNX21, ACOT8, Metazoa_SRP, ZSWIM3, ZSWIM1, SPATA25, NEURL2, CTSA, AL008726.1, PLTP, AL162458.1, PCIF1, ZNF335, FTLP1, MMP9, SLC12A5-AS1, SLC12A5, NCOA5, RPL13P2, CD40, AL031687.1, CDH22, SLC35C2, AL133227.1, ELMO2, ZNF663P, AL031686.1, MKRN7P, ZNF840P, ZNF334, OCSTAMP.
- chr20:47,160,838–57,122,745, 183 genes, copy number 5 (broad region; genes not listed).
- chr20:57,442,742–60,653,784, 70 genes, copy number 5 (broad region; genes not listed).
- chr22:16,405,330–41,621,043, 1,078 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,215. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
